Gene-level copy-number profile of specimen HCM-STAN-0777-C25-85A from HCMI case HCM-STAN-0777-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.0 years (24,820 days).
Specimen HCM-STAN-0777-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a2a0eedf-f466-407b-a1cd-3c39abc7cf9b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0777-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/2a9b89f6-542a-42ee-93a4-3d5f29b0d937

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,736; copy number 2: 20,531; copy number 3: 24,513; copy number 4: 11,135; copy number 5: 910; copy number 6: 76; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,841,357, 4 genes: PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–1): PRAMEF2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:105,959–202,303, 2 genes, copy number 7 (within-gene range 3–7): AC253576.1, ZNF718.

Autosomal genes at a single copy (total copy number 1): 1,189. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
